Surgical pathology report (de-identified scan), TCGA case TCGA-85-A53L, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-A53L-01A (Primary Tumor).

Gross Description: Tumor is located in right middle lobe, ill - margins with 7x6x5cm in size, soft and gray surface.

Subcarinal and segmental lymph nodes are 0.5cm in maximum size, black in color.

Microscopic Description: Tumor tissue arranges in the form of group or sheets or trabeculae or sheets with central necrosis of tumor cells, invading in benign bronchus tissue. The malignant cells have moderate, eosinophilic cytoplasm. The nuclei are enlarged, variability in size and shape, containing coarse clumped chromatin with prominent nucleoli. Mitotic figures are common. Tumor is predominantly invasion of lymphocytes and fibrous

Diagnosis Details: Squamous cell carcinoma, grade III

Comments:

Formatted Path Reports: LUNG TISSUE CHECKLIST

Specimen type: Lobectomy

Tumor site: Lung

Tumor size: 7 x 6 x 5 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Poorly differentiated

Tumor extent: Not specified

Other tumor nodules: Not specified

Lymph nodes: 0/2 positive for metastasis (Subcarinal and segmental lymph node 0/2)

Lymphatic invasion: Present

Venous invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: Right- middle

1CD-0-3
carcinoma, squamous cell, NIS 8070/3
Site: Lung, @ middle lobe c34.2
hw
11/20/12

HIFAA Discrepancy		X

Source: NCI Genomic Data Commons file d3127a89-d4fc-4639-836e-ad68d59a39b4 (TCGA-85-A53L.3671CFAF-C10F-40F9-9FE4-0ADB566433E2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).